Gene-level copy-number profile of tumor specimen ALCH-B2PS-TTP1-A from ALCHEMIST case ALCH-B2PS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.8 years (28,770 days).
Specimen ALCH-B2PS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2d736b08-181f-4e64-a958-f2f91c8ed5ec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2PS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/f48ebda4-c912-4ce7-bd36-f7530d9b8597

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 224; copy number 1: 18,469; copy number 2: 32,779; copy number 3: 5,881; copy number 4: 417; copy number 5: 623.

Homozygous deletions (total copy number 0; autosomes only): 224 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr6:105,919–10,478,502, 189 genes (broad region; genes not listed).
- chr8:8,086,022–8,096,726, 3 genes: AC105233.2, MIR548I3, RPS3AP31.
- chr9:64,369,394–64,473,826, 6 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1.
- chr10:4,962,436–5,135,226, 8 genes (within-gene range 0–1): U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.
- chr10:133,362,485–133,391,694, 4 genes (within-gene range 0–1): ECHS1, MIR3944, AL360181.4, PAOX.
- chr11:44,726,465–44,951,306, 2 genes (within-gene range 0–2): TSPAN18, TP53I11.
- chr11:94,706,431–94,876,748, 1 gene (within-gene range 0–2): AMOTL1.
- chr16:15,703,135–16,143,257, 10 genes (within-gene range 0–2): MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1, RPL17P40.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 618 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:156,037,701–156,539,138, 1 gene, copy number 5 (within-gene range 3–5): KCNAB1.
- chr3:156,143,570–156,540,627, 1 gene, copy number 5 (within-gene range 3–5): AC091607.2.
- chr3:156,441,157–190,892,429, 537 genes, copy number 5 (broad region; genes not listed).
- chr11:1,983,237–2,001,470, 6 genes, copy number 5 (within-gene range 2–5): MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr17:508,668–721,717, 1 gene, copy number 5 (within-gene range 4–5): VPS53.
- chr17:616,002–2,303,785, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18,032. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
